Gene-level copy-number profile of tumor specimen TCGA-N8-A4PN-01A from TCGA case TCGA-N8-A4PN, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinosarcoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Age at diagnosis: 68.6 years (25,064 days).
Specimen TCGA-N8-A4PN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.24b89211-0b30-44bb-91c9-c80382ae3cd4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N8-A4PN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1c67b25e-8634-47ff-a28c-d04c956ba338

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 73; copy number 2: 12,625; copy number 3: 24,636; copy number 4: 14,884; copy number 5: 6,083; copy number 6: 552; copy number 7: 447; copy number 8: 460; copy number 9: 18; copy number 10: 34; copy number 11: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N8-A4PN-01A-11D-A28Q-01): tumor purity 0.96, ploidy 3.35, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 963 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,729,581–203,955,780, 11 genes, copy number 10: SNORA77, LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3.
- chr3:130,560,334–153,377,562, 381 genes, copy number 7 (broad region; genes not listed).
- chr3:153,431,856–153,502,697, 2 genes, copy number 7: LINC02877, RNU6-901P.
- chr3:185,476,496–186,362,234, 14 genes, copy number 7: TMEM41A, AC099661.1, LIPH, SENP2, AC133473.1, IGF2BP2, IGF2BP2-AS1, MIR548AQ, TRA2B, NMRAL2P, ETV5, Metazoa_SRP, ETV5-AS1, DGKG.
- chr6:64,377,795–64,733,837, 3 genes, copy number 7: AL357375.1, HNRNPDP2, AL355357.1.
- chr12:49,770,960–50,480,004, 31 genes, copy number 8: LSM6P2, NCKAP5L, BCDIN3D-AS1, BCDIN3D, AC131157.1, RPL35AP28, FAIM2, LINC02395, LINC02396, AQP2, AC025154.2, AC025154.1, AQP5, AQP6, RACGAP1, ASIC1, SMARCD1, GPD1, COX14, AC074032.1, CERS5, LIMA1, AC008147.2, AC008147.3, AC008147.1, MIR1293, RNU6-1093P, AC008147.4, FAM186A, AC090058.1, LARP4.
- chr12:52,821,408–53,727,745, 51 genes, copy number 8 (within-gene range 6–8): KRT79, AC107016.1, KRT78, RPL7P41, KRT8, KRT18, EIF4B, AC068888.2, AC068888.1, TNS2, MIR6757, SPRYD3, IGFBP6, SOAT2, VTI1BP3, RNU6-333P, HIGD1AP1, EIF4A1P4, CSAD, AC073573.1, ZNF740, ITGB7, RARG, AC021072.1, MFSD5, ESPL1, PFDN5, AC073611.1, MYG1-AS1, MYG1, AAAS, SP7, SP1, AMHR2, PRR13, AC023509.1, PCBP2, PCBP2-OT1, AC023509.4, MAP3K12, AC023509.3, TARBP2, ATF7-NPFF, NPFF, ATF7, AC023509.2, AC023509.6, AC023509.5, ATP5MC2, AC073594.1, CALCOCO1.
- chr12:53,746,337–53,762,104, 2 genes, copy number 8: CISTR, AC076968.1.
- chr19:28,065,267–30,085,893, 48 genes, copy number 8–9: AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5.
- chr19:30,228,290–30,872,507, 4 genes, copy number 11: ZNF536, AC011504.1, AC011478.1, AC011507.1.
- chr19:32,875,925–33,067,433, 6 genes, copy number 10: CEP89, RPL31P60, FAAP24, RHPN2, AC008521.1, AC008521.2.
- chr19:38,730,187–39,435,949, 47 genes, copy number 7: CAPN12, AC022144.1, LGALS7, LGALS7B, RNU6-140P, LGALS4, ECH1, AC008982.1, AC104534.1, HNRNPL, AC008982.2, RINL, AC011455.1, SIRT2, NFKBIB, CCER2, SARS2, AC011455.2, MRPS12, ERVK9-11, FBXO17, AC011455.8, FBXO27, AC010605.1, ACP7, PAK4, AC011443.1, NCCRP1, SYCN, IFNL3P1, IFNL3, IFNL4, MSRB1P1, IFNL4P1, IFNL2, IFNL1, LRFN1, GMFG, AC011445.1, SAMD4B, RN7SL566P, PAF1, MED29, ZFP36, MIR4530, PLEKHG2, RPS16.
- chr20:30,278,906–33,913,336, 117 genes, copy number 8 (broad region; genes not listed).
- chr20:34,194,569–34,698,790, 19 genes, copy number 8 (within-gene range 3–8): ASIP, XPOTP1, AL035458.2, AL035458.1, AHCY, AL356299.2, AL356299.1, ITCH, Y_RNA, CDC42P1, ITCH-AS1, ITCH-IT1, MIR644A, FDX1P1, AL109923.1, DYNLRB1, Y_RNA, MAP1LC3A, PIGU.
- chr20:41,991,140–44,522,085, 50 genes, copy number 8–10: AL049812.2, AL049812.1, AL049812.3, PTPRT, AL035666.1, AL031656.1, PTPRT-AS1, RN7SKP100, AL021395.1, RN7SL666P, PPIAP21, AL021395.2, AL031681.1, RNU6-743P, EIF4EBP2P1, Y_RNA, SRSF6, AL031681.2, RNU6-1251P, L3MBTL1, Z98752.2, Z98752.3, Z98752.1, SGK2, Z98752.4, IFT52, RPL27AP, MYBL2, GTSF1L, RNU6-639P, LINC01728, TOX2, RN7SL443P, JPH2, AL035447.1, OSER1, OSER1-DT, GDAP1L1, FITM2, R3HDML, Y_RNA, AL117382.1, HNF4A, HNF4A-AS1, AL117382.2, MIR3646, LINC01620, RPL37AP1, TTPAL, SERINC3.
- chr20:47,478,214–51,131,667, 97 genes, copy number 8 (broad region; genes not listed).
- chr20:52,972,358–53,741,797, 15 genes, copy number 9: TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1.
- chr20:63,286,808–64,313,132, 65 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 73. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
